Somatic mutation profile of tumor specimen TARGET-20-PARGTL-09A (aliquot TARGET-20-PARGTL-09A-02D) from TARGET case TARGET-20-PARGTL, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.8 years (5,787 days).
Specimen TARGET-20-PARGTL-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a5924557-0692-4161-a2c0-4cd5f25076c5.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PARGTL-14A (Bone Marrow Normal), aliquot TARGET-20-PARGTL-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d784808c-c4c8-4c59-b3fa-fecbe6f07a08

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DHX15 | c.664C>G p.R222G | Missense Mutation (SNP) | VAF 104/253 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61028061, COSV61028114, COSV61028271; called by muse, mutect2, varscan2
- DHX15 | c.467T>G p.F156C | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2
- CHEK2 | c.1242C>T p.H414= (on ENST00000382580 / NM_001005735.2; = p.H371= on NM_007194.4) | Silent (SNP) | VAF 61/165 reads (37%) | catalogued as rs876659094; ClinVar: likely benign; called by muse, mutect2, varscan2
